Somatic mutation profile of tumor specimen TCGA-AG-3742-01A (aliquot TCGA-AG-3742-01A-11D-1657-10) from TCGA case TCGA-AG-3742, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 85.1 years (31,078 days).
Specimen TCGA-AG-3742-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03d8ca47-9676-42cc-88f1-b4063ddd53bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3742-11A (Solid Tissue Normal), aliquot TCGA-AG-3742-11A-01D-1657-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f920d28c-aa9e-4048-b88d-18fda510ad45

The open-access MAF lists 160 somatic variants for this specimen: 120 protein-altering or splice-affecting, 38 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 38, Nonsense Mutation 7, Frame Shift Del 3, RNA 2, Splice Region 2, Frame Shift Ins 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 46/123 reads (37%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.3907C>T p.Q1303* | Nonsense Mutation (SNP) | VAF 68/171 reads (40%) | hotspot (GDC flag); catalogued as CM994441, COSV57323819; called by muse, mutect2, varscan2
- F8 | c.6545G>A p.R2182H | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852466, CM015870, CM111360, CM940403, COSV57704301; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1745C>T p.S582L (on ENST00000281708 / NM_001349798.2; = p.S502L on NM_018315.5) | Missense Mutation (SNP) | VAF 83/120 reads (69%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV104381731, COSV55890836; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 39/103 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 396/678 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 24/47 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775465354, COSV62789520; called by muse, mutect2, varscan2
- ABCB9 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.773); catalogued as COSV54890048; called by muse, mutect2, varscan2
- ACMSD | c.810T>A p.D270E | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.413); catalogued as rs1454080515, COSV51605461; called by muse, mutect2, varscan2
- ACSM5 | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100089180, COSV100089257; called by muse, mutect2
- AL592490.1 | c.2270C>A p.S757Y | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV101308241; called by muse, mutect2
- ALAS2 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 61/95 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs752853849, COSV58188274, COSV58190561; called by muse, mutect2, varscan2
- AMER2 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV63436019; called by muse, mutect2, varscan2
- ANO7 | c.1453G>A p.E485K (on ENST00000274979; = p.E431K on NM_001370694.2) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as rs780268640, COSV51468046; called by muse, mutect2, varscan2
- APOB | c.7538G>A p.R2513Q | Missense Mutation (SNP) | VAF 89/196 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs554045156, COSV51929537; called by muse, mutect2, varscan2
- ARHGEF1 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as rs1555847009, COSV61526211; called by muse, varscan2
- C12orf43 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as COSV56566244; called by muse, mutect2, varscan2
- CACNA1E | c.4925G>A p.R1642Q | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.274); catalogued as rs1381608974, COSV100705568, COSV62381870; called by muse, varscan2
- CALD1 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62645080; called by muse, mutect2, varscan2
- CAPN5 | c.1351C>T p.R451W (on ENST00000456580; = p.R411W on NM_004055.5) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1264178900, COSV53685553; called by muse, mutect2, varscan2
- CCDC183 | c.459C>G p.N153K | Missense Mutation (SNP) | VAF 87/141 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1389112641, COSV62011997; called by muse, mutect2, varscan2
- CCIN | c.1746C>G p.C582W | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.981); catalogued as COSV100631900, COSV58725519, COSV58725694; called by muse, mutect2
- CDKL5 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs1465351962, COSV66110154; called by muse, mutect2, varscan2
- CERS5 | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs547919626, COSV58188290; called by muse, mutect2, varscan2
- CREB3L4 | c.70T>C p.S24P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV99676829; called by muse, mutect2, varscan2
- CT47A6 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.913); catalogued as COSV101342110; called by muse, mutect2, varscan2
- DCAF12L2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1229366218, COSV63580270, COSV63581169; called by muse, mutect2, varscan2
- DNAH5 | c.12631G>T p.E4211* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as rs762673561, COSV54204698, COSV54216995; called by muse, mutect2, varscan2
- DNAJB5 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as rs772171150, COSV56624578, COSV56624822; called by muse, mutect2, varscan2
- DOCK5 | c.4272G>T p.Q1424H | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV52395816; called by muse, mutect2, varscan2
- ENC1 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs778976207, COSV56628540; called by muse, mutect2, varscan2
- EPPK1 | c.3709G>C p.A1237P | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.372); catalogued as COSV101599900; called by muse, varscan2
- FADS2 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1565338575, COSV53896683, COSV53897455; called by muse, mutect2, varscan2
- FBN3 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs554641249, COSV54453139; called by muse, mutect2, varscan2
- FOXF2 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52525010; called by muse, mutect2, varscan2
- FREM1 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV66517571, COSV66518874; called by muse, mutect2, varscan2
- GALNT17 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as rs367865697, COSV61147246; called by muse, mutect2, varscan2
- GNA15 | c.417G>A p.W139* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as COSV53584873, COSV53585093; called by muse, mutect2, varscan2
- GPR12 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs758632134, COSV67343989; called by muse, mutect2, varscan2
- GPR83 | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.974); catalogued as COSV54717404; called by muse, mutect2, varscan2
- GRPEL2 | c.400G>T p.E134* | Nonsense Mutation (SNP) | VAF 39/89 reads (44%) | catalogued as COSV61387280, COSV61387406; called by muse, mutect2, varscan2
- GSTZ1 | c.604T>C p.S202P | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as rs1566677059, COSV99374533; called by muse, mutect2, varscan2
- HTR3A | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs34111946; called by muse, mutect2, varscan2
- ICE1 | c.5281G>T p.A1761S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56818849; called by muse, mutect2
- ILDR2 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359594941, COSV54831021; called by muse, mutect2, varscan2
- INTS6 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.368); catalogued as COSV100247173; called by muse, varscan2
- ITIH6 | c.3661C>A p.Q1221K | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV54486312; called by muse, mutect2, varscan2
- ITSN1 | c.4036A>C p.K1346Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV67156775; called by muse, mutect2, varscan2
- JAK3 | c.2224C>T p.Q742* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV71685468; called by muse, mutect2, varscan2
- JMJD1C | c.6442G>T p.D2148Y | Missense Mutation (SNP) | VAF 18/451 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV100550699; called by muse, mutect2
- KCNV2 | c.1087G>A p.G363S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.82); PolyPhen benign (0.013); catalogued as rs566426805, COSV66055496, COSV66055524; called by muse, mutect2, varscan2
- KCTD1 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.517); catalogued as rs1456643085, COSV58683390; called by muse, mutect2, varscan2
- KHDC1 | c.614C>T p.A205V (on ENST00000370384 / NM_001251874.2; = p.A132V on NM_030568.5) | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.255); catalogued as COSV57614054; called by muse, mutect2, varscan2
- KIAA1210 | c.4442A>C p.K1481T | Missense Mutation (SNP) | VAF 109/381 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV68175358; called by muse, mutect2, varscan2
- KIAA1755 | c.1441C>A p.Q481K | Missense Mutation (SNP) | VAF 120/174 reads (69%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV54073534; called by muse, mutect2, varscan2
- LPA | c.3287+1G>A p.X1096_splice | Splice Site (SNP) | VAF 32/97 reads (33%) | catalogued as rs767906902, COSV60309190; called by muse, mutect2, varscan2
- LRIG3 | c.2278A>T p.S760C | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV57860751; called by muse, mutect2, varscan2
- LRP6 | c.2641G>A p.V881I | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs767098954, COSV53783132, COSV53786022; called by muse, mutect2, varscan2
- LUZP2 | c.149G>T p.R50I | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.696); catalogued as COSV61195080, COSV61197164; called by muse, mutect2, varscan2
- MEFV | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs775374556, COSV54818449; ClinVar: likely benign; called by muse, mutect2, varscan2
- METTL16 | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV54011913; called by muse, mutect2, varscan2
- MUC16 | c.28168G>A p.A9390T | Missense Mutation (SNP) | VAF 86/209 reads (41%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.086); catalogued as COSV67443751; called by muse, mutect2, varscan2
- MUC6 | c.3089C>T p.S1030L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1255461548, COSV70133299; called by muse, mutect2, varscan2
- N4BP2 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs778863068, COSV54698840; called by muse, mutect2, varscan2
- NOVA1 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 94/146 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV57472163; called by muse, mutect2, varscan2
- NRK | c.2354A>T p.Q785L | Missense Mutation (SNP) | VAF 215/384 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV54589546; called by muse, mutect2, varscan2
- OOSP2 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 66/135 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs758882178, COSV53928078; called by muse, mutect2, varscan2
- OR2M2 | c.761C>A p.A254E | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100677266; called by muse, mutect2
- OR5M10 | c.932G>A p.C311Y | Missense Mutation (SNP) | VAF 115/297 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754935666, COSV73242238; called by muse, mutect2, varscan2
- OR5M10 | c.931T>C p.C311R | Missense Mutation (SNP) | VAF 119/303 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs201834242, COSV73242239; called by muse, mutect2, varscan2
- OTOA | c.1864del p.W622Gfs*36 (on ENST00000286149; = p.W608Gfs*36 on NM_144672.4) | Frame Shift Del (DEL) | VAF 136/370 reads (37%) | catalogued as COSV53749029; called by mutect2, pindel, varscan2
- OTOGL | c.2515G>C p.A839P (on ENST00000547103; = p.A830P on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV72005587; called by muse, mutect2, varscan2
- PANX3 | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV52511027; called by muse, mutect2, varscan2
- PCDHA11 | c.2090del p.V697Gfs*3 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | catalogued as COSV56476986; called by mutect2, pindel, varscan2
- PCDHGA6 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV53896526, COSV99536529; called by muse, mutect2, varscan2
- PDHA2 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs777635144, COSV54778400; called by muse, mutect2, varscan2
- PHIP | c.2585A>G p.N862S | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.588); catalogued as COSV51501329; called by muse, mutect2, varscan2
- PIGG | c.2816C>A p.T939K (on ENST00000453061 / NM_001127178.3; = p.T931K on NM_017733.4) | Missense Mutation (SNP) | VAF 139/363 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV56316065; called by muse, mutect2, varscan2
- PLCXD1 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 121/213 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs139457367, COSV67541469; called by muse, mutect2, varscan2
- PLEKHG5 | c.3127G>A p.V1043I (on ENST00000400915 / NM_001042663.3; = p.V1006I on NM_020631.6) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV61067610; called by muse, mutect2, varscan2
- POM121 | c.1973C>T p.P658L (on ENST00000434423; = p.P393L on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs782016223, COSV99988733; called by muse, mutect2, varscan2
- POTEF | c.2782G>A p.A928T | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); catalogued as rs768744009, COSV62539607; called by muse, varscan2
- PPIP5K2 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1554205218, COSV58602342; called by muse, mutect2, varscan2
- PRF1 | c.134G>T p.G45V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM040245, COSV64615820; called by muse, mutect2, varscan2
- PSG11 | c.269T>C p.I90T | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs747475165, COSV60453537; called by muse, mutect2
- PZP | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs369009345; called by muse, mutect2, varscan2
- RPL7 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as rs1257776173, COSV53581189; called by muse, mutect2, varscan2
- RTN2 | c.1035G>A p.V345= | Splice Region (SNP) | VAF 5/13 reads (38%) | catalogued as COSV99839105; called by muse, mutect2, varscan2
- SCN8A | c.2989C>A p.L997I | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as COSV61976321; called by muse, mutect2, varscan2
- SELENOO | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs201826328; called by muse, mutect2, varscan2
- SEZ6L | c.2294G>A p.R765Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs756050832, COSV50657839, COSV50660193; called by muse, mutect2, varscan2
- SKIV2L | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.16); catalogued as rs768031925, COSV61712729; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A18 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV99721973, COSV99722482; called by muse, mutect2, varscan2
- SMOC1 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 64/88 reads (73%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs763002694, COSV62759440; called by muse, mutect2, varscan2
- SNX20 | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.09); catalogued as rs770462562, COSV56056557; called by muse, mutect2, varscan2
- SPEM2 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 9/11 reads (82%) | catalogued as rs1291606823, COSV60366061; called by muse, mutect2, varscan2
- ST7L | c.19G>A p.V7M | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV54144150; called by muse, mutect2, varscan2
- STARD8 | c.2645G>A p.R882Q | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs768839540, COSV52921529; called by muse, mutect2, varscan2
- SYBU | c.1336G>A p.V446M (on ENST00000276646 / NM_001099754.2; = p.V445M on NM_017786.6) | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV52614063; called by muse, varscan2
- SYBU | c.1334T>A p.I445K (on ENST00000276646 / NM_001099754.2; = p.I444K on NM_017786.6) | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV52614105; called by muse, varscan2
- SYNE1 | c.23704G>A p.A7902T (on ENST00000367255 / NM_182961.4; = p.A7831T on NM_033071.3) | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.924); catalogued as rs372990463; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYTL2 | c.1273G>C p.E425Q | Missense Mutation (SNP) | VAF 133/349 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.051); catalogued as COSV60355671; called by muse, mutect2, varscan2
- TACR3 | c.530C>T p.T177M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.872); catalogued as rs777243337, CM1210494, COSV59197805; called by muse, mutect2, varscan2
- TRIB3 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs143437909; called by muse, mutect2, varscan2
- TRIM25 | c.1449G>T p.E483D | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57543145; called by muse, mutect2, varscan2
- TTN | c.30116T>A p.V10039D (on ENST00000591111; = p.V9112D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 144/341 reads (42%) | PolyPhen benign (0.046); catalogued as COSV59880345; called by muse, varscan2
- ULK1 | c.1807C>T p.R603W | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs142452051; called by muse, mutect2, varscan2
- VSIG1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1241189147, COSV54257578; called by muse, mutect2, varscan2
- WDR11 | c.1554C>A p.V518= | Splice Region (SNP) | VAF 24/49 reads (49%) | catalogued as COSV54785298; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2708G>T p.R903L | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.213); catalogued as COSV60155530; called by muse, mutect2, varscan2
- ZNF467 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs560346109, COSV57371933; called by muse, mutect2, varscan2
- ZNF479 | c.718C>A p.P240T | Missense Mutation (SNP) | VAF 72/270 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.173); catalogued as COSV58635758, COSV58638380; called by muse, mutect2, varscan2
- ZNF672 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1208618649, COSV60637226; called by muse, mutect2, varscan2
- AGAP4 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- KCNE5 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.251); called by muse, varscan2
- KCNH8 | c.169del p.R57Efs*23 | Frame Shift Del (DEL) | VAF 62/199 reads (31%) | called by mutect2, pindel, varscan2
- MAOA | c.1198_1200dup p.E400dup | In Frame Ins (INS) | VAF 61/272 reads (22%) | called by mutect2, pindel, varscan2
- SPACA5B | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 398/1411 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- ZFP36L2 | c.503dup p.C168Wfs*306 | Frame Shift Ins (INS) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- AKAP8L | c.1137G>A p.Q379= | Silent (SNP) | VAF 51/124 reads (41%) | catalogued as COSV101275831; called by muse, mutect2, varscan2
- ARHGAP22 | c.1491G>A p.A497= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV50932545; called by muse, mutect2, varscan2
- BCLAF1 | c.897A>G p.R299= | Silent (SNP) | VAF 38/118 reads (32%) | catalogued as COSV62140327; called by muse, mutect2, varscan2
- CDH11 | c.1740G>A p.P580= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs759807372, COSV51750977; called by muse, mutect2, varscan2
- CNGB1 | c.1464C>T p.T488= | Silent (SNP) | VAF 53/136 reads (39%) | catalogued as rs372219689; called by muse, mutect2, varscan2
- CPPED1 | c.777C>T p.L259= | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as rs1477563700, COSV55495581; called by muse, mutect2, varscan2
- CRHR2 | c.1110G>A p.V370= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs1405764856, COSV59263688; called by muse, mutect2, varscan2
- CTAG2 | c.198C>T p.G66= | Silent (SNP) | VAF 66/109 reads (61%) | catalogued as rs1557241785, COSV55993941; called by muse, mutect2, varscan2
- CYP7B1 | c.1431T>C p.D477= | Silent (SNP) | VAF 45/123 reads (37%) | catalogued as COSV59582280; called by muse, mutect2, varscan2
- DGKK | c.3537C>T p.S1179= | Silent (SNP) | VAF 119/207 reads (57%) | catalogued as rs782318161, COSV101053108; called by muse, mutect2, varscan2
- DYSF | c.4713C>T p.A1571= | Silent (SNP) | VAF 55/149 reads (37%) | catalogued as rs375485030; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- FAT4 | c.13461G>A p.A4487= | Silent (SNP) | VAF 44/125 reads (35%) | catalogued as rs776669972, COSV58671097; called by muse, mutect2, varscan2
- HIVEP2 | c.5145C>T p.T1715= | Silent (SNP) | VAF 62/144 reads (43%) | catalogued as rs753009520, COSV50005469; called by muse, mutect2, varscan2
- IDO1 | c.507G>A p.L169= | Silent (SNP) | VAF 65/104 reads (63%) | catalogued as COSV53712911; called by muse, mutect2, varscan2
- ITGAD | c.2886G>C p.L962= | Silent (SNP) | VAF 61/174 reads (35%) | catalogued as COSV54931477; called by muse, mutect2, varscan2
- JCAD | c.3999G>A p.P1333= | Silent (SNP) | VAF 68/161 reads (42%) | catalogued as rs771380894, COSV64757873; called by muse, mutect2, varscan2
- KAT14 | c.1398C>T p.Y466= | Silent (SNP) | VAF 24/32 reads (75%) | catalogued as rs577238938, COSV66606599; called by muse, mutect2, varscan2
- KCNC1 | c.249C>T p.C83= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV56391450; called by muse, mutect2, varscan2
- MTCL1 | c.4269C>T p.D1423= (on ENST00000306329 / NM_001378206.1; = p.D1104= on NM_015210.4) | Silent (SNP) | VAF 26/44 reads (59%) | catalogued as rs772605367, COSV60403007; called by muse, mutect2, varscan2
- MUC5B | c.3246G>A p.Q1082= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV101500540; called by muse, mutect2
- NPTX2 | c.1152C>T p.R384= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs748698114, COSV55716163; called by muse, mutect2, varscan2
- NUCB1 | c.360C>T p.D120= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as COSV54385002; called by muse, mutect2, varscan2
- OR6Y1 | c.363T>A p.A121= | Silent (SNP) | VAF 44/121 reads (36%) | catalogued as COSV56928105; called by muse, mutect2, varscan2
- P4HA1 | c.1125G>A p.T375= | Silent (SNP) | VAF 88/230 reads (38%) | catalogued as rs773651613, COSV54958559; called by muse, mutect2, varscan2
- PCDHA6 | c.2076G>A p.A692= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV65341712; called by muse, mutect2, varscan2
- PCDHGA3 | c.1668C>T p.N556= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as rs745711073, COSV53986997; called by muse, mutect2, varscan2
- PLCD3 | c.1068G>T p.L356= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV59558538; called by muse, mutect2, varscan2
- PLXNA1 | c.5259G>T p.V1753= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV52522051; called by muse, mutect2, varscan2
- PTPRH | c.3312C>T p.N1104= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs770213055, COSV54742508; called by muse, mutect2, varscan2
- RNF113A | c.207G>A p.K69= | Silent (SNP) | VAF 36/151 reads (24%) | catalogued as COSV101007079; called by muse, mutect2, varscan2
- RTL10 | c.219C>T p.G73= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs200786836, COSV100144251; called by muse, mutect2, varscan2
- SLC14A2 | c.2505C>T p.I835= | Silent (SNP) | VAF 23/30 reads (77%) | catalogued as rs139049054; called by muse, mutect2, varscan2
- SYBU | c.1335A>T p.I445= (on ENST00000276646 / NM_001099754.2; = p.I444= on NM_017786.6) | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as COSV52614084; called by muse, varscan2
- TUBGCP6 | c.2058A>G p.A686= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs753236977, COSV50536408; called by muse, mutect2, varscan2
- ULBP2 | c.450C>G p.L150= | Silent (SNP) | VAF 120/347 reads (35%) | catalogued as COSV66265084; called by muse, mutect2, varscan2
- UNG | c.300G>A p.K100= (on ENST00000242576 / NM_080911.3; = p.K91= on NM_003362.4) | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as rs773617744, COSV54356470; called by muse, mutect2, varscan2
- XKR7 | c.861G>A p.S287= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as rs780540300, COSV73812878; called by muse, mutect2, varscan2
- ZP3 | c.654G>A p.V218= (on ENST00000394857 / NM_001110354.2; = p.V167= on NM_007155.6) | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV60630322; called by muse, mutect2, varscan2
- FAM86C1P | n.361G>C | RNA (SNP) | VAF 21/100 reads (21%) | catalogued as COSV60637757; called by muse, mutect2, varscan2
- ZNF658B | n.1789T>C | RNA (SNP) | VAF 18/56 reads (32%) | called by mutect2, varscan2
